Somatic mutation profile of tumor specimen TCGA-EM-A1CS-01A (aliquot TCGA-EM-A1CS-01A-11D-A13W-08) from TCGA case TCGA-EM-A1CS, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 55.5 years (20,284 days).
Specimen TCGA-EM-A1CS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0752f2e-e8c8-4bd7-8f87-e3019f3e83bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1CS-10A (Blood Derived Normal), aliquot TCGA-EM-A1CS-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0810a9c9-4658-4905-85b7-5a58362bbf45

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as COSV50787992; called by muse, mutect2, varscan2
- AMBP | c.130T>G p.W44G | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54325363; called by muse, mutect2, varscan2
- ARMCX3 | c.338C>A p.S113* | Nonsense Mutation (SNP) | VAF 13/127 reads (10%) | catalogued as COSV57871499; called by muse, mutect2, varscan2
- LBP | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs544709874, COSV54143109; called by muse, mutect2, varscan2
- MUC5AC | c.16647G>A p.S5549= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs774598914, COSV100611624; called by muse, varscan2
